Gene-level copy-number profile of tumor specimen TCGA-LD-A7W6-01A from TCGA case TCGA-LD-A7W6, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Upper-inner quadrant of breast; AJCC pathologic stage: Stage IIB; Age at diagnosis: 55.0 years (20,077 days).
Specimen TCGA-LD-A7W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b52a570c-9511-40f3-911e-de079cdbb1ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LD-A7W6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f450f7b6-c841-4b8a-a58b-6f2a77ba2a67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,822; copy number 2: 51,391; copy number 3: 2,801; copy number 4: 197; copy number 5: 115; copy number 6: 138; copy number 7: 300; copy number 9: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LD-A7W6-01A-81D-A350-01): tumor purity 0.59, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 607 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,405,439–37,599,858, 6 genes, copy number 5: AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4.
- chr8:37,734,761–41,032,998, 78 genes, copy number 7–9 (broad region; genes not listed).
- chr11:68,460,731–71,252,577, 67 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:74,454,841–76,444,687, 72 genes, copy number 5 (broad region; genes not listed).
- chr19:11,639,754–16,328,685, 276 genes, copy number 7 (broad region; genes not listed).
- chr19:17,049,729–17,521,288, 38 genes, copy number 6 (within-gene range 3–6): HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS, AC010618.2.
- chr19:17,747,718–19,060,311, 70 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
